Surgical pathology report (de-identified scan), TCGA case TCGA-SX-A71S, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Mayo Clinic Arizona, specimen TCGA-SX-A71S-01A (Primary Tumor).

Result Type: Surgical Pathology Report
Result Date:
Performed By:
Encounter Info:

Surgical Pathology Report

ICD-O-3
Carcinoma, papillary
renal cell 8/6/13
Site @ Kidney NOS
C64.9
JW 8/9/13

Surgical Pathology Report

DIAGNOSIS:

- A. Posterior medial margin: Renal cortical tissue. Negative for malignancy.
B. Tumor base #1: Renal cortical tissue. Negative for malignancy.
C. Tumor base #2: Renal cortical tissue. Negative for malignancy.
D. Left kidney tumor, excision: Renal cell carcinoma, papillary type, 2.0 cm in greatest dimension, Fuhrman nuclear grade 1 (of 4). The tumor focally abuts the inked margin. No invasion of adipose tissue is identified.

CLINICAL INFORMATION:
Left perihilar mass.

SPECIMEN(S):

- A:Posterior medial margin
B:Tumor base #1
C:Tumor base #2
D:Left kidney tumor

PRELIMINARY INTRAOPERATIVE DIAGNOSIS:

Intraoperative Pathologist(s):

- A. Posterior medial margin, frozen section diagnosis: Negative.
B. Tumor base #1, frozen section diagnosis: Negative.
C. Tumor base #2, frozen section diagnosis: Negative.
D. Left kidney tumor, frozen section diagnosis: Renal neoplasm. Favor papillary renal cell carcinoma, type 1 versus less likely metanephric adenoma. Tumor cells are at ink.

GROSS DESCRIPTION:

Performed by

A. Received fresh labeled and "posterior medial margin" is a tan portion of tissue, 0.3 x 0.3 x 0.1 cm. All submitted following frozen section in one cassette labeled

B. Received fresh labeled and "tumor base #1" is a tan portion of tissue, 0.4 x 0.3 x 0.2 cm. All submitted following frozen section in one cassette labeled -B1.

C. Received fresh labeled and "tumor base #2" is a portion of tissue, 0.4 x 0.2 x 0.2 cm. All submitted following frozen section in one cassette labeled

D. Received fresh labeled and "left kidney tumor" is a spherical nodule, 2.0 cm in greatest dimension. There is a portion of lobulated soft fat that is present on the surface opposite the inked base. The cut surface of the nodule has uniform, pale yellow consistency throughout. All submitted in four cassettes labeled D1) Frozen section sample; D2-D3) remainder of nodule and adjacent fat; D4) mirror image of sample submitted for research

Support for the diagnosis in this case may have included the use of immunohistochemistry tests that were developed and whose performance characteristics were determined by

. They have not been cleared or approved by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 8f9ff5ab-99b0-461a-bab1-deccc18c5ce5 (TCGA-SX-A71S.3CFF32CE-20A4-4D1D-B338-8845CF9F86E6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).